Somatic mutation profile of cancer-model specimen HCM-CSHL-0773-C50-85N (3D Organoid, passage 10; aliquot HCM-CSHL-0773-C50-85N-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0773-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 62.3 years (22,742 days).
Specimen HCM-CSHL-0773-C50-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2aa4179f-97d9-4f02-bc45-c737ecd95f1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0773-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0773-C50-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14b52402-1c6a-47d1-a05e-af04828f3d26

The open-access MAF lists 211 somatic variants for this specimen: 151 protein-altering or splice-affecting, 54 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 54, Nonsense Mutation 12, Intron 4, Frame Shift Del 4, In Frame Del 3, 3'UTR 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 216/336 reads (64%) | hotspot (GDC flag); SIFT tolerated (0.51); PolyPhen benign (0.366); catalogued as COSV55875690, COSV55899999; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 354/513 reads (69%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>G p.C135G | Missense Mutation (SNP) | VAF 426/428 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADCY8 | c.3010G>T p.G1004* | Nonsense Mutation (SNP) | VAF 65/593 reads (11%) | catalogued as COSV99650680; called by muse, mutect2, varscan2
- ADGRV1 | c.4385G>T p.G1462V | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67989180; called by muse, mutect2, varscan2
- C1QTNF1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 492/492 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778432442; called by muse, mutect2, varscan2
- C2orf69 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV60666337; called by muse, mutect2, varscan2
- CADPS2 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 147/334 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs774598697; called by muse, mutect2, varscan2
- CARM1 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 299/299 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.697); catalogued as rs1215450621; called by muse, mutect2, varscan2
- CCNB3 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 268/690 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV52072336, COSV99329441; called by muse, mutect2, varscan2
- CDH3 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 198/198 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as COSV50573469; called by muse, mutect2, varscan2
- CFHR5 | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 26/635 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV56818634; called by muse, mutect2
- CFP | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 139/382 reads (36%) | catalogued as COSV55949636, COSV55949827; called by muse, mutect2, varscan2
- CLMP | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 201/412 reads (49%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs753089200; called by muse, mutect2, varscan2
- CPQ | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 338/491 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV55154714; called by muse, mutect2, varscan2
- CSMD3 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as COSV99850760; called by muse, mutect2, varscan2
- DDRGK1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 174/385 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751324528, COSV63226722; called by muse, mutect2, varscan2
- DEDD2 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 210/416 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs750217130, COSV60143245; called by muse, mutect2, varscan2
- DIP2B | c.2977G>C p.E993Q | Missense Mutation (SNP) | VAF 127/316 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs532000455; called by muse, mutect2, varscan2
- DNAH3 | c.3193G>C p.E1065Q | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV54556445; called by muse, mutect2, varscan2
- ENAH | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 128/443 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1422405670, COSV52872881; called by muse, mutect2, varscan2
- GLP2R | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as rs766910205, COSV52328713; called by muse, mutect2
- GPR6 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 58/428 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1299973521; called by muse, mutect2, varscan2
- H2BC21 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 181/614 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV58611970; called by muse, mutect2, varscan2
- HPX | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 193/409 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as rs1328976234; called by muse, mutect2, varscan2
- IBA57 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 303/967 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs539907686; called by muse, mutect2, varscan2
- ITGAV | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 194/194 reads (100%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1013173268; called by muse, varscan2
- JAG2 | c.3674C>T p.A1225V | Missense Mutation (SNP) | VAF 201/421 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs587606450, COSV59312525; called by muse, mutect2, varscan2
- KNDC1 | c.4206G>C p.K1402N | Missense Mutation (SNP) | VAF 174/381 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV58844222; called by muse, mutect2, varscan2
- KRTAP19-3 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.095); catalogued as rs749197798; called by muse, mutect2, varscan2
- MAEA | c.661G>A p.A221T (on ENST00000303400 / NM_001017405.3; = p.A180T on NM_005882.5) | Missense Mutation (SNP) | VAF 151/285 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs868375875; called by muse, mutect2, varscan2
- MAGEB6 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 453/785 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs200287901, COSV66872530; called by muse, mutect2, varscan2
- MUC5B | c.10358C>G p.T3453S | Missense Mutation (SNP) | VAF 141/971 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs529974907; called by muse, mutect2, varscan2
- MYO5C | c.4558G>A p.E1520K | Missense Mutation (SNP) | VAF 123/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1024104735, COSV55904819; called by muse, mutect2, varscan2
- OR2C1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 158/327 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148753562; called by muse, mutect2, varscan2
- PPP2R2B | c.1172G>A p.R391Q (on ENST00000394409; = p.R457Q on NM_181674.2) | Missense Mutation (SNP) | VAF 194/428 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.268); catalogued as rs779246443, COSV60764427; called by muse, mutect2, varscan2
- PRR14L | c.4084G>C p.E1362Q | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.408); catalogued as COSV57883878; called by muse, mutect2, varscan2
- PTN | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100781068; called by muse, mutect2
- SFXN3 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs570135686; called by muse, mutect2
- SIN3A | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 167/423 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs747451113, COSV51244008; called by muse, mutect2
- SNAPC4 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 195/373 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773993107; called by muse, mutect2, varscan2
- SORCS1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 198/458 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs546084462, COSV53840434; called by muse, mutect2, varscan2
- STK19 | c.1062C>T p.C354= (on ENST00000375333 / NM_032454.1; = p.C350= on NM_004197.1) | Splice Region (SNP) | VAF 52/235 reads (22%) | catalogued as rs1481769706; called by muse, mutect2, varscan2
- SUFU | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 206/409 reads (50%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs758001170; called by muse, mutect2, varscan2
- SWT1 | c.2270C>G p.S757C | Missense Mutation (SNP) | VAF 175/526 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV62253771; called by muse, mutect2, varscan2
- THG1L | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 139/252 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51453195; called by muse, mutect2, varscan2
- TMEM41A | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 75/642 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs151156113; called by muse, mutect2, varscan2
- TRIM41 | c.1146C>G p.I382M | Missense Mutation (SNP) | VAF 184/348 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV59319459; called by muse, mutect2, varscan2
- TTC13 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 162/461 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as rs778831776; called by muse, mutect2, varscan2
- UPK3B | c.334C>T p.R112C (on ENST00000257632; = p.R57C on NM_001347684.2) | Missense Mutation (SNP) | VAF 249/778 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as rs773449795; called by muse, mutect2, varscan2
- WASHC2A | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 197/422 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs1329833413; called by muse, varscan2
- XIRP2 | c.6150G>A p.M2050I (on ENST00000628543; = p.M2225I on NM_152381.6) | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1312908648, COSV99744986; called by muse, varscan2
- XIRP2 | c.6529G>T p.D2177Y (on ENST00000628543; = p.D2352Y on NM_152381.6) | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV54713699, COSV99737875; called by muse, mutect2, varscan2
- ABCA5 | c.4249A>T p.T1417S | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- ABCB9 | c.1717T>C p.Y573H (on ENST00000280560 / NM_019625.4; = p.Y530H on NM_019624.3) | Missense Mutation (SNP) | VAF 34/582 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- AP3B2 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 25/651 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.219); called by muse, mutect2
- BAHD1 | c.1640C>G p.S547* | Nonsense Mutation (SNP) | VAF 251/658 reads (38%) | called by muse, mutect2, varscan2
- BPTF | c.122C>G p.S41W | Missense Mutation (SNP) | VAF 287/557 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- C12orf45 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 241/437 reads (55%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- C14orf39 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 201/390 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CABIN1 | c.1946C>G p.T649S | Missense Mutation (SNP) | VAF 258/259 reads (100%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARNS1 | c.1666G>T p.G556W | Missense Mutation (SNP) | VAF 54/612 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CATSPERE | c.2638C>T p.P880S | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC7 | c.2017C>G p.H673D | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNF | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 151/322 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CEP41 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 158/361 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP43 | c.2992G>C p.E998Q | Missense Mutation (SNP) | VAF 174/360 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP54 | c.6725-1G>A p.X2242_splice | Splice Site (SNP) | VAF 85/187 reads (45%) | called by muse, mutect2, varscan2
- CHMP2B | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 136/466 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CHST7 | c.1135G>T p.V379L | Missense Mutation (SNP) | VAF 342/802 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CLDN15 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 27/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CLEC16A | c.846C>G p.H282Q | Missense Mutation (SNP) | VAF 188/397 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLIP3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 217/429 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- CNTNAP5 | c.1707T>A p.Y569* | Nonsense Mutation (SNP) | VAF 184/185 reads (99%) | called by muse, mutect2, varscan2
- CUL2 | c.697T>C p.S233P | Missense Mutation (SNP) | VAF 109/237 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CYLC1 | c.1035A>T p.K345N | Missense Mutation (SNP) | VAF 249/445 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DCHS1 | c.6598C>G p.Q2200E | Missense Mutation (SNP) | VAF 170/334 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DGKI | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMXL2 | c.5604A>T p.K1868N | Missense Mutation (SNP) | VAF 251/415 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DNAH2 | c.13054G>A p.E4352K | Missense Mutation (SNP) | VAF 217/513 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- EDAR | c.982A>T p.K328* | Nonsense Mutation (SNP) | VAF 151/151 reads (100%) | called by muse, mutect2, varscan2
- EEF1A1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 117/175 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- EIF3F | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EML5 | c.5143G>T p.D1715Y (on ENST00000380664; = p.D1723Y on NM_183387.3) | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM189A2 | c.750_754dup p.P252Qfs*20 | Frame Shift Ins (INS) | VAF 98/104 reads (94%) | called by mutect2, varscan2
- FAM20C | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 250/469 reads (53%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FLG | c.3806G>C p.S1269T | Missense Mutation (SNP) | VAF 167/486 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- FREM1 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FTHL17 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 396/732 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GDF6 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 225/645 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GLUD2 | c.1061A>G p.Q354R | Missense Mutation (SNP) | VAF 182/481 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GMPPB | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 263/529 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GPRASP2 | c.381_384delinsC p.Q127_A128delinsH | In Frame Del (DEL) | VAF 136/419 reads (32%) | called by pindel, varscan2*
- GRM1 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 208/307 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- HLA-DMB | c.617A>C p.D206A | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- HNF4G | c.889A>C p.S297R (on ENST00000354370 / NM_001330561.2; = p.S344R on NM_004133.5) | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- HOXB5 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 34/660 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.441); called by muse, mutect2
- ITM2A | c.182C>A p.S61* | Nonsense Mutation (SNP) | VAF 256/451 reads (57%) | called by muse, mutect2, varscan2
- ITPR3 | c.5860G>A p.E1954K | Missense Mutation (SNP) | VAF 130/215 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- KCTD2 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1109 | c.1529C>G p.P510R | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIF15 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KMT5C | c.394A>C p.N132H | Missense Mutation (SNP) | VAF 169/340 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- KPNB1 | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 203/203 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- KRTAP10-4 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 258/2650 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KRTAP10-6 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 164/656 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LMTK2 | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- LRRC10B | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 299/567 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LTBR | c.1161_1195del p.I388Lfs*25 | Frame Shift Del (DEL) | VAF 230/632 reads (36%) | called by mutect2, pindel, varscan2
- MAML1 | c.2605_2622del p.Q869_L874del | In Frame Del (DEL) | VAF 226/541 reads (42%) | called by mutect2, pindel, varscan2
- MDN1 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 150/203 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MED25 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 164/337 reads (49%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- MOCS1 | c.974A>G p.N325S | Missense Mutation (SNP) | VAF 109/175 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NAA10 | c.345C>A p.N115K | Missense Mutation (SNP) | VAF 252/396 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NADSYN1 | c.939G>C p.L313F | Missense Mutation (SNP) | VAF 179/430 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAV3 | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 222/479 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NBDY | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 237/462 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- PAWR | c.15_21del p.Y6Pfs*82 | Frame Shift Del (DEL) | VAF 134/333 reads (40%) | called by mutect2, pindel, varscan2
- PGR | c.2367G>A p.M789I | Missense Mutation (SNP) | VAF 108/220 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PHKA1 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 382/673 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PJVK | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 116/116 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- PLA2G4A | c.2082T>A p.H694Q | Missense Mutation (SNP) | VAF 159/504 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- POLA1 | c.3109G>C p.E1037Q | Missense Mutation (SNP) | VAF 151/403 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPM1E | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 220/458 reads (48%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.034); called by muse, varscan2
- PPP1R26 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 275/527 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRKCSH | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.059); called by muse, mutect2
- PSD2 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 179/384 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- PTCD1 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 174/191 reads (91%) | SIFT tolerated (0.31); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RASAL1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 196/384 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- RNPEPL1 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 288/288 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RPS6KA4 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 213/461 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SDAD1 | c.1694G>T p.R565I | Missense Mutation (SNP) | VAF 214/214 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SEMA4F | c.2214_2235del p.G739Lfs*12 | Frame Shift Del (DEL) | VAF 165/399 reads (41%) | called by mutect2, pindel, varscan2
- SIX5 | c.1314T>G p.F438L | Missense Mutation (SNP) | VAF 345/632 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLAIN1 | c.1363C>T p.Q455* (on ENST00000466548; = p.Q192* on NM_144595.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 59/243 reads (24%) | called by muse, mutect2, varscan2
- SLFN11 | c.2116C>T p.Q706* | Nonsense Mutation (SNP) | VAF 251/251 reads (100%) | called by muse, mutect2, varscan2
- SMC1A | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 183/476 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SQOR | c.1251G>A p.M417I | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2
- SRRM5 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 261/564 reads (46%) | called by muse, mutect2, varscan2
- TAF11L2 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 215/482 reads (45%) | called by muse, mutect2, varscan2
- TBC1D17 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 119/263 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TBC1D3F | c.1193del p.P398Rfs*67 | Frame Shift Del (DEL) | VAF 3/9 reads (33%) | called by mutect2, varscan2
- TCHH | c.2387G>C p.R796T | Missense Mutation (SNP) | VAF 264/871 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- TLN2 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 167/454 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMEM190 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TNNC1 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 116/562 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TOP2B | c.2779C>A p.Q927K (on ENST00000264331 / NM_001330700.2; = p.Q922K on NM_001068.3) | Missense Mutation (SNP) | VAF 66/737 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.101); called by muse, mutect2
- TRIM55 | c.1031_1033del p.E344del | In Frame Del (DEL) | VAF 138/319 reads (43%) | called by pindel, varscan2
- WDR93 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 212/406 reads (52%) | called by muse, mutect2
- XIRP2 | c.6090C>A p.N2030K (on ENST00000628543; = p.N2205K on NM_152381.6) | Missense Mutation (SNP) | VAF 114/114 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, varscan2
- ZNF770 | c.996T>G p.Y332* | Nonsense Mutation (SNP) | VAF 111/318 reads (35%) | called by muse, mutect2, varscan2
- ACACB | c.2499G>A p.L833= | Silent (SNP) | VAF 168/367 reads (46%) | called by muse, mutect2, varscan2
- ARMC3 | c.2385C>T p.F795= | Silent (SNP) | VAF 35/222 reads (16%) | catalogued as COSV53067616; called by muse, mutect2, varscan2
- B3GAT2 | c.492C>A p.L164= | Silent (SNP) | VAF 262/376 reads (70%) | called by mutect2, varscan2
- CSH2 | c.357C>T p.L119= | Silent (SNP) | VAF 142/406 reads (35%) | called by muse, varscan2
- CUX2 | c.2355C>T p.F785= | Silent (SNP) | VAF 368/735 reads (50%) | catalogued as COSV55637281; called by muse, varscan2
- DSCAML1 | c.2115C>T p.I705= (on ENST00000321322; = p.I645= on NM_020693.4) | Silent (SNP) | VAF 222/547 reads (41%) | catalogued as rs997538419, COSV58398181; called by muse, mutect2, varscan2
- ETNK2 | c.1053G>A p.Q351= | Silent (SNP) | VAF 156/494 reads (32%) | called by muse, mutect2, varscan2
- FAT4 | c.1299C>G p.S433= | Silent (SNP) | VAF 230/230 reads (100%) | catalogued as rs764678411; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBLN2 | c.45C>T p.G15= | Silent (SNP) | VAF 318/1012 reads (31%) | called by muse, mutect2, varscan2
- FH | c.90C>A p.G30= | Silent (SNP) | VAF 218/751 reads (29%) | called by muse, mutect2, varscan2
- GABRR2 | c.1254C>T p.N418= | Silent (SNP) | VAF 130/447 reads (29%) | catalogued as rs370972483, COSV68764359; called by muse, mutect2, varscan2
- GDPD1 | c.81G>A p.P27= | Silent (SNP) | VAF 178/404 reads (44%) | catalogued as COSV99405102; called by muse, mutect2, varscan2
- GPR3 | c.636C>T p.L212= | Silent (SNP) | VAF 289/290 reads (100%) | catalogued as rs1433948651; called by muse, mutect2, varscan2
- HNRNPL | c.642C>T p.I214= | Silent (SNP) | VAF 171/346 reads (49%) | catalogued as rs368381708; called by muse, mutect2, varscan2
- IBA57 | c.273T>G p.A91= | Silent (SNP) | VAF 285/888 reads (32%) | called by mutect2, varscan2
- IGDCC4 | c.2367C>T p.P789= | Silent (SNP) | VAF 227/403 reads (56%) | called by muse, mutect2, varscan2
- INVS | c.48A>C p.S16= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- ITGA5 | c.660T>A p.V220= | Silent (SNP) | VAF 149/351 reads (42%) | called by muse, mutect2, varscan2
- JPH2 | c.423C>T p.Y141= | Silent (SNP) | VAF 274/614 reads (45%) | catalogued as rs1167675574, COSV65903494; called by muse, mutect2, varscan2
- KIAA1109 | c.13266A>T p.V4422= | Silent (SNP) | VAF 128/128 reads (100%) | called by muse, mutect2, varscan2
- KLC3 | c.903T>C p.Y301= | Silent (SNP) | VAF 288/601 reads (48%) | called by muse, mutect2, varscan2
- KMT5C | c.393G>A p.K131= | Silent (SNP) | VAF 168/332 reads (51%) | called by muse, mutect2, varscan2
- KRT85 | c.297G>A p.S99= | Silent (SNP) | VAF 404/800 reads (51%) | catalogued as rs780000267; called by muse, mutect2
- LAMA4 | c.4905C>T p.F1635= (on ENST00000230538 / NM_001105206.3; = p.F1628= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 131/197 reads (66%) | called by muse, mutect2, varscan2
- LRRC10B | c.720C>T p.R240= | Silent (SNP) | VAF 313/627 reads (50%) | called by muse, mutect2, varscan2
- MICU1 | c.1293G>A p.K431= (on ENST00000361114 / NM_001195518.2; = p.K437= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 160/323 reads (50%) | called by muse, mutect2, varscan2
- MOXD1 | c.252G>A p.R84= | Silent (SNP) | VAF 116/296 reads (39%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.147C>A p.L49= | Silent (SNP) | VAF 248/520 reads (48%) | catalogued as COSV66934137; called by muse, mutect2, varscan2
- NADSYN1 | c.940C>T p.L314= | Silent (SNP) | VAF 179/427 reads (42%) | catalogued as rs775485997; called by muse, mutect2, varscan2
- NNT | c.1449C>G p.L483= | Silent (SNP) | VAF 111/258 reads (43%) | catalogued as COSV52924967; called by muse, mutect2, varscan2
- OR2T11 | c.453C>T p.L151= | Silent (SNP) | VAF 172/379 reads (45%) | catalogued as rs373592782; called by muse, mutect2, varscan2
- PODXL | c.1461C>T p.L487= (on ENST00000378555 / NM_001018111.3; = p.L455= on NM_005397.4) | Silent (SNP) | VAF 28/253 reads (11%) | called by muse, mutect2, varscan2
- RASGEF1B | c.141C>T p.A47= | Silent (SNP) | VAF 176/176 reads (100%) | called by muse, mutect2, varscan2
- RC3H1 | c.3321G>A p.L1107= | Silent (SNP) | VAF 184/602 reads (31%) | called by muse, mutect2, varscan2
- RHBDF1 | c.1128G>A p.V376= | Silent (SNP) | VAF 365/712 reads (51%) | catalogued as rs1435189021; called by muse, mutect2, varscan2
- SEMA6C | c.1947C>T p.L649= | Silent (SNP) | VAF 275/831 reads (33%) | called by muse, mutect2, varscan2
- SERPINB10 | c.1143G>A p.R381= | Silent (SNP) | VAF 170/365 reads (47%) | catalogued as rs1268316820; called by muse, mutect2, varscan2
- SHROOM3 | c.5220G>A p.V1740= | Silent (SNP) | VAF 128/128 reads (100%) | called by muse, varscan2
- SLC13A2 | c.543A>G p.E181= | Silent (SNP) | VAF 192/192 reads (100%) | called by muse, mutect2, varscan2
- SLC26A6 | c.912G>A p.G304= | Silent (SNP) | VAF 85/246 reads (35%) | called by muse, mutect2, varscan2
- SPDYC | c.483C>T p.F161= | Silent (SNP) | VAF 231/489 reads (47%) | called by muse, mutect2, varscan2
- SPTBN4 | c.4347C>T p.L1449= | Silent (SNP) | VAF 112/232 reads (48%) | called by muse, mutect2, varscan2
- SRRM3 | c.456C>T p.R152= | Silent (SNP) | VAF 299/920 reads (33%) | catalogued as rs1353962511, COSV100418738; called by muse, mutect2, varscan2
- SSMEM1 | c.390G>A p.R130= | Silent (SNP) | VAF 254/502 reads (51%) | catalogued as COSV99927754; called by muse, mutect2, varscan2
- STARD9 | c.9972A>T p.P3324= | Silent (SNP) | VAF 140/446 reads (31%) | called by muse, mutect2, varscan2
- TGIF2LX | c.687C>T p.A229= | Silent (SNP) | VAF 184/313 reads (59%) | catalogued as rs763936281; called by muse, mutect2, varscan2
- TMEM130 | c.606G>A p.G202= | Silent (SNP) | VAF 54/228 reads (24%) | called by muse, mutect2, varscan2
- TNK2 | c.1383C>T p.S461= | Silent (SNP) | VAF 67/821 reads (8%) | called by muse, mutect2
- WWC3 | c.2709G>T p.T903= | Silent (SNP) | VAF 464/844 reads (55%) | catalogued as COSV66506965; called by muse, mutect2, varscan2
- YTHDF1 | c.843G>A p.P281= | Silent (SNP) | VAF 257/257 reads (100%) | catalogued as rs542852740; called by muse, mutect2, varscan2
- ZNF43 | c.1083G>A p.K361= | Silent (SNP) | VAF 218/448 reads (49%) | catalogued as rs1209343822, COSV61685404; called by muse, mutect2, varscan2
- ZNF564 | c.1074T>A p.T358= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- ZNF792 | c.1845C>A p.V615= | Silent (SNP) | VAF 180/388 reads (46%) | called by muse, mutect2, varscan2
- ZYG11B | c.306C>T p.F102= | Silent (SNP) | VAF 235/235 reads (100%) | catalogued as COSV53756677; called by muse, mutect2, varscan2
- CLN5 | c.*511G>C | 3'UTR (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100842369; called by muse, mutect2, varscan2
- GALNT12 | c.*479G>A | 3'UTR (SNP) | VAF 181/182 reads (99%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-3463C>T | Intron (SNP) | VAF 170/774 reads (22%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+9961A>C | Intron (SNP) | VAF 158/331 reads (48%) | called by muse, mutect2, varscan2
- NISCH | c.1528+108C>G | Intron (SNP) | VAF 242/500 reads (48%) | catalogued as rs1235558630; called by muse, mutect2, varscan2
- TSHR | c.692+177A>G | Intron (SNP) | VAF 136/364 reads (37%) | called by muse, mutect2
